Somatic mutation profile of tumor specimen MMRF_2667_1_BM_CD138pos (aliquot MMRF_2667_1_BM_CD138pos_T1_KHS5U_L13784) from MMRF case MMRF_2667, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.4 years (19,155 days).
Specimen MMRF_2667_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95259930-9a62-43f7-8ef8-17541114c8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2667_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2667_1_PB_WBC_C3_KHS5U_L13785; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f6d8ed3-f08d-468f-b377-e821f0ecbc18

The open-access MAF lists 72 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 19, Silent 8, Intron 7, 3'Flank 4, Nonsense Mutation 2, Frame Shift Ins 2, 5'UTR 2, RNA 2, 5'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.1211dup p.N404Kfs*3 | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | catalogued as rs764163418; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs769442021, COSV61656573; called by muse, mutect2
- CACNA1I | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1048987823, COSV60800273; called by muse, mutect2, varscan2
- CAMK2A | c.1339G>A p.A447T (on ENST00000348628 / NM_171825.2; = p.A458T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs748774194, COSV100652046; called by muse, mutect2
- CAPN5 | c.1238G>A p.R413H (on ENST00000456580; = p.R373H on NM_004055.5) | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782751635; called by muse, mutect2, varscan2
- CSMD2 | c.5194G>A p.A1732T | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.916); catalogued as COSV99595680; called by muse, mutect2, varscan2
- IGHJ3 | c.32T>G p.M11R | Missense Mutation (SNP) | VAF 27/34 reads (79%) | PolyPhen benign (0); catalogued as rs181332275; called by muse, varscan2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- PPP2R2D | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs781827357, COSV70778901; called by muse, mutect2, varscan2
- PTPRN | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 159/332 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs756735224, COSV55348618; called by muse, mutect2, varscan2
- SART1 | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 28/367 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV56712865; called by muse, mutect2
- SEC14L1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66720731; called by muse, mutect2, varscan2
- ANKRD30A | c.285A>T p.R95S (on ENST00000611781; = p.R39S on NM_052997.2) | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- ARHGAP5 | c.3718-1G>A p.X1240_splice | Splice Site (SNP) | VAF 5/122 reads (4%) | called by muse, mutect2
- ARPIN | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 86/703 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DLG5 | c.2730_2731insAC p.R911Tfs*79 | Frame Shift Ins (INS) | VAF 96/236 reads (41%) | called by mutect2, pindel, varscan2
- FN1 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FSD2 | c.1871G>A p.W624* | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- GTF2IRD2B | c.1352A>T p.K451I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- PTPN13 | c.3498T>A p.N1166K (on ENST00000411767 / NM_080683.3; = p.N1147K on NM_006264.3) | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- RFX8 | c.307A>T p.K103* (on ENST00000646446; = p.K32* on NM_001145664.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- RNF113B | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 154/171 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPS6KB2 | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 171/398 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT16 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YWHAB | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.178); called by muse, mutect2
- ZDBF2 | c.1942C>A p.L648I | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZFYVE28 | c.2101G>C p.A701P | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- DENND5A | c.1314G>A p.L438= | Silent (SNP) | VAF 69/141 reads (49%) | called by muse, mutect2, varscan2
- EPHB4 | c.1989C>T p.S663= | Silent (SNP) | VAF 22/406 reads (5%) | catalogued as COSV62269717; called by muse, mutect2
- GOLGB1 | c.1734A>G p.L578= | Silent (SNP) | VAF 15/214 reads (7%) | called by muse, mutect2
- GRM1 | c.2772C>T p.C924= | Silent (SNP) | VAF 18/514 reads (4%) | catalogued as COSV51139743, COSV51201331; called by muse, mutect2
- GTPBP3 | c.211C>T p.L71= | Silent (SNP) | VAF 32/422 reads (8%) | catalogued as rs368983548; called by muse, mutect2
- MGAM | c.3012T>A p.S1004= | Silent (SNP) | VAF 17/445 reads (4%) | called by muse, mutect2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 12/231 reads (5%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
- SZT2 | c.8664G>A p.E2888= (on ENST00000634258 / NM_001365999.1; = p.E2831= on NM_015284.4) | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- AC008060.1 | n.527G>A | RNA (SNP) | VAF 85/209 reads (41%) | catalogued as rs558926928; called by muse, mutect2, varscan2
- AC124067.4 | n.963G>A | RNA (SNP) | VAF 25/272 reads (9%) | called by muse, mutect2
- ADCY2 | c.*1443C>T | 3'UTR (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- AGPAT4 | c.*2797G>T | 3'UTR (SNP) | VAF 66/167 reads (40%) | called by muse, mutect2, varscan2
- ANHX | c.*207del | 3'UTR (DEL) | VAF 67/180 reads (37%) | called by mutect2, pindel, varscan2
- ANKRD13C | c.*478C>T | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- BMP6 | c.*1230_*1262del | 3'UTR (DEL) | VAF 38/129 reads (29%) | called by mutect2, pindel
- C4orf50 | c.*1936G>A | 3'UTR (SNP) | VAF 48/124 reads (39%) | catalogued as rs939658651; called by muse, mutect2
- C8orf74 | c.49-916A>C | Intron (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- CDON | c.*2748T>A | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- CEP126 | c.*3132C>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | catalogued as rs1444466601; called by muse, mutect2, varscan2
- CNTRL | c.*157T>A | 3'UTR (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- FAM219A | c.*1307C>T | 3'UTR (SNP) | VAF 18/245 reads (7%) | called by muse, mutect2
- FBXO32 | c.*2323G>A | 3'UTR (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-1472G>A | Intron (SNP) | VAF 170/341 reads (50%) | catalogued as rs976199463; called by muse, mutect2, varscan2
- HLA-DQA1 | c.*474T>C | 3'UTR (SNP) | VAF 40/58 reads (69%) | called by muse, mutect2
- INTS1 | c.-82C>T | 5'UTR (SNP) | VAF 94/171 reads (55%) | catalogued as rs773206518; called by muse, varscan2
- KIF21B | chr1:200971345 T>A | 3'Flank (SNP) | VAF 107/242 reads (44%) | called by muse, mutect2, varscan2
- MAP9 | c.*833G>C | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- MED28 | c.*1820_*1864del | 3'UTR (DEL) | VAF 66/540 reads (12%) | called by mutect2, pindel
- MIR4739 | chr17:79707535 C>A | 5'Flank (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- MRPL18 | c.52+148G>A | Intron (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100365010; called by muse, mutect2, varscan2
- PFKP | c.621-13G>A | Intron (SNP) | VAF 46/536 reads (9%) | called by muse, mutect2
- PHTF2 | c.1740+113del | Intron (DEL) | VAF 5/26 reads (19%) | catalogued as rs200782700, COSV50324232; called by pindel, varscan2
- PPP1R3A | c.*638C>A | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, varscan2
- PTPN4 | c.*6352G>T | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143625010 C>A | 3'Flank (SNP) | VAF 30/33 reads (91%) | catalogued as COSV62025151; called by muse, mutect2, varscan2
- SORD | c.100+20G>T | Intron (SNP) | VAF 35/190 reads (18%) | catalogued as rs375753112; called by muse, mutect2, varscan2
- TET2 | c.3409+1161A>G | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- TMEM201 | c.*813G>C | 3'UTR (SNP) | VAF 40/576 reads (7%) | called by muse, mutect2
- TPD52L3 | chr9:6330983 C>T | 3'Flank (SNP) | VAF 76/147 reads (52%) | catalogued as rs759599244; called by muse, mutect2, varscan2
- UBXN2B | c.*170G>A | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- VPS26C | c.*1364T>A | 3'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- ZFP36L2 | chr2:43222365 G>C | 3'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- ZNF282 | c.-9A>G | 5'UTR (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- ZNF578 | chr19:52451264 A>C | 5'Flank (SNP) | VAF 64/169 reads (38%) | catalogued as rs1480429931; called by muse, mutect2, varscan2
